Somatic mutation profile of tumor specimen MP2PRT-PARNPN-TMP1-A (aliquot MP2PRT-PARNPN-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARNPN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,272 days).
Specimen MP2PRT-PARNPN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 425e4951-3f84-428b-ac53-847fd2fb76eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARNPN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARNPN-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a2b4f00-fe81-4b5f-a1ae-675d1f45671f

The open-access MAF lists 13 somatic variants for this specimen: 5 protein-altering or splice-affecting, 8 silent.
By variant classification: Silent 8, Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMB2 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 220/550 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs200316162; called by muse, mutect2, varscan2
- ANO5 | c.2651T>G p.L884* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- BRS3 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- HDAC2 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFX6 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- BFSP1 | c.1410C>T p.H470= | Silent (SNP) | VAF 68/576 reads (12%) | catalogued as rs78102780; called by muse, mutect2, varscan2
- CAPNS2 | c.351C>T p.D117= | Silent (SNP) | VAF 23/338 reads (7%) | catalogued as COSV50894924; called by muse, mutect2
- DYSF | c.3405C>T p.F1135= | Silent (SNP) | VAF 43/752 reads (6%) | catalogued as rs778088008, COSV50268450; called by muse, mutect2
- GLDN | c.33C>T p.D11= | Silent (SNP) | VAF 261/735 reads (36%) | catalogued as rs1386509110; called by muse, mutect2, varscan2
- MMUT | c.1464A>G p.G488= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- NXPE1 | c.48T>C p.S16= | Silent (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- SLC22A31 | c.591G>T p.G197= | Silent (SNP) | VAF 173/455 reads (38%) | called by muse, mutect2, varscan2
- SLIT3 | c.4092C>T p.C1364= | Silent (SNP) | VAF 254/657 reads (39%) | catalogued as rs745443967; called by muse, mutect2
